Somatic mutation profile of cancer-model specimen HCM-SANG-0293-C15-85A (3D Organoid; aliquot HCM-SANG-0293-C15-85A-01D-A78J-36), derived from the primary tumor of HCMI case HCM-SANG-0293-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS.
Specimen HCM-SANG-0293-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 373ddc99-4bef-4695-ad09-5735e7f1fcce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0293-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0293-C15-10A-01D-A78J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c572961-f536-468d-94ee-1aeee1c2d943

The open-access MAF lists 314 somatic variants for this specimen: 169 protein-altering or splice-affecting, 100 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 154, Silent 100, Intron 27, 3'UTR 6, RNA 5, Nonsense Mutation 5, 5'UTR 5, Splice Site 4, Frame Shift Del 2, In Frame Ins 2, 5'Flank 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.1888T>G p.F630V | Missense Mutation (SNP) | VAF 233/544 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100957836, COSV100958101, COSV66328724; called by muse, mutect2, varscan2
- TP53 | c.559+1G>A p.X187_splice | Splice Site (SNP) | VAF 169/175 reads (97%) | hotspot (GDC flag); catalogued as rs1131691042, CS137624, COSV52670017, COSV52686439, COSV52695669; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAM19 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.454); catalogued as rs199716249, COSV57426292; called by muse, mutect2, varscan2
- ADAMTS16 | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs550837516, COSV56982433; called by muse, mutect2, varscan2
- AKAP6 | c.6130G>T p.D2044Y | Missense Mutation (SNP) | VAF 76/78 reads (97%) | SIFT tolerated (0.35); PolyPhen benign (0.34); catalogued as COSV55219960; called by muse, mutect2, varscan2
- ASXL3 | c.4658C>T p.P1553L | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs374446513, COSV99327301; called by muse, mutect2, varscan2
- BAHCC1 | c.1496C>A p.S499Y | Missense Mutation (SNP) | VAF 163/306 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as COSV100311895, COSV57032672; called by muse, mutect2, varscan2
- CACNA1C | c.3097G>A p.V1033M | Missense Mutation (SNP) | VAF 205/701 reads (29%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.997); catalogued as COSV59725271, COSV59737416; called by muse, mutect2, varscan2
- CECR2 | c.3589C>T p.R1197C (on ENST00000342247 / NM_001290047.2; = p.R1013C on NM_001290046.1) | Missense Mutation (SNP) | VAF 74/74 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52839127; called by muse, mutect2, varscan2
- CFAP74 | c.2635G>A p.A879T | Missense Mutation (SNP) | VAF 123/225 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1216864666; called by muse, mutect2, varscan2
- CHRD | c.2393G>A p.R798Q | Missense Mutation (SNP) | VAF 79/157 reads (50%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.603); catalogued as rs147576679; called by muse, mutect2, varscan2
- CTNNB1 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 259/503 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1323014360; called by muse, mutect2, varscan2
- DACH2 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 85/87 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64173724; called by muse, mutect2, varscan2
- DMRT2 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 141/144 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52402414; called by muse, mutect2, varscan2
- DNAH3 | c.335A>G p.N112S | Missense Mutation (SNP) | VAF 254/583 reads (44%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.091); catalogued as rs772303514, COSV54547378; called by muse, mutect2, varscan2
- DNAH7 | c.3936-2A>G p.X1312_splice | Splice Site (SNP) | VAF 52/107 reads (49%) | catalogued as rs1434867656; called by muse, mutect2
- DUSP22 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs377115548; called by muse, mutect2, varscan2
- EIF5B | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs767626569, COSV99176871; called by muse, mutect2, varscan2
- EOMES | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 13/318 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1449192017, COSV99841712; called by muse, mutect2
- ERVV-2 | c.1198G>T p.A400S | Missense Mutation (SNP) | VAF 28/293 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs567708768; called by muse, mutect2
- FAM13B | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 63/125 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs750549898; called by muse, mutect2, varscan2
- FAT4 | c.11494C>T p.R3832C | Missense Mutation (SNP) | VAF 159/360 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.337); catalogued as rs571765492, COSV58690828; called by muse, mutect2, varscan2
- FBXO31 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 104/189 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61148964; called by muse, mutect2, varscan2
- H1-0 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 471/489 reads (96%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs780382320; called by muse, mutect2, varscan2
- HOMEZ | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 102/106 reads (96%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.987); catalogued as rs750934524, COSV62537447; called by muse, mutect2, varscan2
- IER5L | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1477396220; called by muse, mutect2
- IL21R | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 128/277 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs374987749, COSV100559717; called by muse, mutect2, varscan2
- INTS10 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 91/92 reads (99%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs747479028; called by muse, mutect2, varscan2
- ITIH1 | c.398C>A p.A133D | Missense Mutation (SNP) | VAF 156/158 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56254960, COSV99835078; called by muse, mutect2, varscan2
- JAG2 | c.191A>G p.H64R | Missense Mutation (SNP) | VAF 34/340 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1364331833, COSV59306384; called by muse, varscan2
- KCNB2 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 120/296 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73050150; called by muse, mutect2, varscan2
- KCNMA1 | c.1334A>G p.N445S | Missense Mutation (SNP) | VAF 179/384 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs925304267; called by muse, mutect2, varscan2
- KRT24 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 95/238 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV52880051; called by muse, mutect2, varscan2
- LOXHD1 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 92/97 reads (95%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs1296741878, COSV59661201; called by muse, mutect2, varscan2
- LRRC38 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 237/536 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1474859336, COSV101065784; called by muse, mutect2, varscan2
- MAP2K3 | c.998C>T p.T333M (on ENST00000342679 / NM_145109.3; = p.T304M on NM_002756.4) | Missense Mutation (SNP) | VAF 94/100 reads (94%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.748); catalogued as rs35755743; called by muse, mutect2, varscan2
- MMP9 | c.1085C>T p.T362I | Missense Mutation (SNP) | VAF 141/321 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs201492378; called by muse, mutect2, varscan2
- MPEG1 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs367733685; called by muse, mutect2, varscan2
- NAV3 | c.2348C>T p.T783M | Missense Mutation (SNP) | VAF 119/119 reads (100%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.828); catalogued as rs745934944, COSV99891334; called by muse, mutect2, varscan2
- NKX6-1 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 226/478 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs1411867652; called by muse, mutect2, varscan2
- NOL4 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 109/230 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.03); catalogued as COSV99305151; called by muse, mutect2, varscan2
- NSD3 | c.2692C>T p.R898C | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100395860; called by muse, mutect2, varscan2
- NTRK2 | c.2192C>T p.T731M (on ENST00000323115 / NM_001369534.1; = p.T747M on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 199/207 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52870633, COSV52876088; called by muse, mutect2, varscan2
- NXPE1 | c.1468T>A p.F490I (on ENST00000424269; = p.F348I on NM_152315.5) | Missense Mutation (SNP) | VAF 386/386 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.394); catalogued as COSV52630874; called by muse, mutect2, varscan2
- OR4S2 | c.539A>C p.H180P | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56748554; called by muse, mutect2, varscan2
- OR51E2 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 191/196 reads (97%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.725); catalogued as COSV67806934; called by muse, mutect2, varscan2
- P3H3 | c.2198G>T p.R733L | Missense Mutation (SNP) | VAF 75/204 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99301791; called by muse, mutect2, varscan2
- PASD1 | c.2181A>C p.Q727H | Missense Mutation (SNP) | VAF 90/92 reads (98%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); catalogued as COSV64858173; called by muse, mutect2, varscan2
- PASK | c.2206G>A p.V736M | Missense Mutation (SNP) | VAF 210/405 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs1297323994; called by muse, mutect2, varscan2
- PCDHB14 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 137/683 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.686); catalogued as rs1554289389; called by muse, mutect2, varscan2
- PCDHGB4 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1470979893; called by muse, mutect2, varscan2
- PI4KA | c.2827G>A p.V943I | Missense Mutation (SNP) | VAF 34/450 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.241); catalogued as rs569814980; called by muse, mutect2
- PI4KB | c.1249C>T p.R417W (on ENST00000368873 / NM_001369623.1; = p.R429W on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 164/349 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs1486195779, COSV55020786; called by muse, mutect2, varscan2
- PIEZO2 | c.6232G>A p.A2078T | Missense Mutation (SNP) | VAF 179/615 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs777548466; called by muse, mutect2, varscan2
- PKP1 | c.779A>C p.K260T | Missense Mutation (SNP) | VAF 161/337 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV55823373; called by muse, mutect2, varscan2
- POP1 | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 258/528 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); catalogued as rs367827296; called by muse, mutect2, varscan2
- POU4F3 | c.196G>A p.V66I | Missense Mutation (SNP) | VAF 213/441 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV57942462; called by muse, mutect2, varscan2
- PPP1CC | c.680T>C p.F227S | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58582406; called by muse, mutect2, varscan2
- PTCH2 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 285/607 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145240049; called by muse, mutect2, varscan2
- PTX3 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 160/310 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs984026408, COSV55821765; called by muse, mutect2, varscan2
- QRICH2 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 151/364 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as rs536269106, COSV53154644; called by muse, mutect2, varscan2
- RAP2B | c.40G>T p.V14L | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as COSV60257214; called by muse, mutect2
- RIMS2 | c.4711C>T p.P1571S (on ENST00000666250 / NM_001348490.2; = p.P1142S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 134/342 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs569582580; called by muse, mutect2, varscan2
- RIPOR2 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 115/120 reads (96%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs781730252, COSV52424481; called by muse, mutect2, varscan2
- SEMA3B | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs781959300; called by muse, mutect2, varscan2
- SLC22A15 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs779957515; called by muse, mutect2, varscan2
- SLC25A19 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 135/287 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); catalogued as rs1306835528; called by muse, mutect2, varscan2
- SMYD5 | c.574C>A p.Q192K | Missense Mutation (SNP) | VAF 86/204 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as rs1352301468; called by muse, mutect2, varscan2
- SPACA9 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 159/167 reads (95%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); catalogued as COSV62521389, COSV62522049; called by muse, mutect2, varscan2
- SPTA1 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 258/501 reads (51%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.601); catalogued as rs1443490977, CD931240, COSV63751408, COSV63756638; called by muse, mutect2, varscan2
- ST6GAL2 | c.781G>A p.V261M | Missense Mutation (SNP) | VAF 39/80 reads (49%) | PolyPhen possibly damaging (0.776); catalogued as rs1037689676, COSV64528241; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 169/177 reads (95%) | PolyPhen possibly damaging (0.692); catalogued as rs369940675; called by muse, mutect2, varscan2
- TGFB3 | c.178A>T p.T60S | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV53170068; called by muse, mutect2
- THEM5 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs370864082; called by muse, mutect2, varscan2
- TICAM1 | c.335C>T p.S112L | Missense Mutation (SNP) | VAF 94/101 reads (93%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs749264598, COSV50229434; called by muse, mutect2, varscan2
- TYR | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 172/357 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as rs200854796, CM135753, COSV54475274; called by muse, mutect2, varscan2
- UBE3C | c.383_386del p.F128Sfs*16 | Frame Shift Del (DEL) | VAF 57/61 reads (93%) | catalogued as rs776968248; called by mutect2, pindel, varscan2
- VLDLR | c.1516G>T p.V506F | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1174280607; called by muse, mutect2
- WNT11 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs374455490; called by muse, mutect2, varscan2
- WNT7A | c.314C>G p.A105G | Missense Mutation (SNP) | VAF 152/327 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV53201034, COSV53202837; called by muse, mutect2, varscan2
- ZBTB17 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 177/341 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs137984913; called by muse, mutect2, varscan2
- ZC3H3 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 142/287 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs756678279, COSV52793478; called by muse, mutect2, varscan2
- ZDHHC15 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 94/104 reads (90%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs775854139, COSV64901200; called by muse, varscan2
- ZNF260 | c.695A>C p.K232T | Missense Mutation (SNP) | VAF 148/313 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as COSV72951157; called by muse, mutect2, varscan2
- ZNF492 | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 143/149 reads (96%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV101513964; called by muse, mutect2, varscan2
- ADAMTS16 | c.2617A>T p.T873S | Missense Mutation (SNP) | VAF 177/359 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ADAMTS20 | c.379C>T p.R127C | Missense Mutation (SNP) | VAF 83/86 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, varscan2
- ADD3 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 152/327 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRL4 | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 50/53 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- AFF2 | c.71C>G p.A24G | Missense Mutation (SNP) | VAF 65/68 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- APBA2 | c.1217G>T p.R406M | Missense Mutation (SNP) | VAF 250/552 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- BEX1 | c.106C>T p.L36F | Missense Mutation (SNP) | VAF 142/151 reads (94%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BPIFB3 | c.1030A>G p.R344G | Missense Mutation (SNP) | VAF 76/76 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- C2CD2L | c.1226A>C p.E409A | Missense Mutation (SNP) | VAF 105/105 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- CC2D2B | c.472G>T p.E158* (on ENST00000646931 / NM_001349008.3; = p.E150* on NM_001130446.3) | Nonsense Mutation (SNP) | VAF 20/270 reads (7%) | called by muse, mutect2
- CDH10 | c.2217A>C p.E739D | Missense Mutation (SNP) | VAF 119/265 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH10 | c.1496A>C p.E499A | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEPT1 | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 140/308 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CLEC4G | c.387C>T p.R129= | Splice Region (SNP) | VAF 163/170 reads (96%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.1522C>A p.P508T | Missense Mutation (SNP) | VAF 121/298 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- COL4A2 | c.3542C>T p.P1181L | Missense Mutation (SNP) | VAF 124/126 reads (98%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CSMD1 | c.1707G>T p.Q569H (on ENST00000520002; = p.Q568H on NM_033225.6) | Missense Mutation (SNP) | VAF 95/194 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CXCL12 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 130/319 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- DRG2 | c.895+1G>T p.X299_splice | Splice Site (SNP) | VAF 84/92 reads (91%) | called by muse, mutect2, varscan2
- FGF19 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 101/257 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- FOXN1 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 119/202 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FUCA2 | c.143C>A p.A48E | Missense Mutation (SNP) | VAF 115/247 reads (47%) | SIFT tolerated (0.79); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GABRA5 | c.1082A>C p.K361T | Missense Mutation (SNP) | VAF 143/280 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- GALNT1 | c.607C>T p.Q203* | Nonsense Mutation (SNP) | VAF 142/325 reads (44%) | called by muse, mutect2, varscan2
- GNA13 | c.580_582dup p.Q194dup | In Frame Ins (INS) | VAF 32/84 reads (38%) | called by mutect2, varscan2
- GOLGA4 | c.2722G>C p.E908Q | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- GPC5 | c.677T>C p.L226P | Missense Mutation (SNP) | VAF 70/72 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GREB1 | c.5429C>G p.A1810G | Missense Mutation (SNP) | VAF 27/516 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2
- HERC2 | c.9748G>C p.V3250L | Missense Mutation (SNP) | VAF 130/325 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HEXIM1 | c.410dup p.E138Rfs*17 | Frame Shift Ins (INS) | VAF 56/146 reads (38%) | called by mutect2, pindel, varscan2
- HNRNPA1 | c.879_881dup p.G297dup | In Frame Ins (INS) | VAF 14/114 reads (12%) | called by pindel, varscan2
- IGFBP7 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 61/138 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IL22RA2 | c.646C>G p.Q216E | Missense Mutation (SNP) | VAF 315/321 reads (98%) | SIFT deleterious (0.02); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- INAVA | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 73/154 reads (47%) | called by muse, mutect2, varscan2
- INPP5B | c.551A>G p.K184R | Missense Mutation (SNP) | VAF 98/210 reads (47%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- JMJD1C | c.6625G>A p.E2209K | Missense Mutation (SNP) | VAF 84/191 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- KCNG4 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2
- KLHL4 | c.1151T>G p.L384R | Missense Mutation (SNP) | VAF 33/35 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- LAMA1 | c.1089T>A p.N363K | Missense Mutation (SNP) | VAF 124/277 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- LARP1 | c.1923C>A p.N641K (on ENST00000518297 / NM_033551.3; = p.N564K on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/183 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- LRP12 | c.273T>G p.S91R | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRP6 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 121/414 reads (29%) | called by muse, mutect2, varscan2
- LRRK2 | c.2887A>C p.K963Q | Missense Mutation (SNP) | VAF 91/93 reads (98%) | SIFT tolerated (0.26); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- MAGI2 | c.1997T>G p.L666R | Missense Mutation (SNP) | VAF 116/227 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAPK9 | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MRTO4 | c.548C>A p.T183N | Missense Mutation (SNP) | VAF 188/437 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- NEK11 | c.1650A>C p.E550D | Missense Mutation (SNP) | VAF 108/250 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NF1 | c.8034A>C p.L2678F (on ENST00000358273 / NM_001042492.3; = p.L2657F on NM_000267.3) | Missense Mutation (SNP) | VAF 169/351 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NIP7 | c.61G>A p.G21R | Missense Mutation (SNP) | VAF 161/328 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- OR7A17 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 139/571 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PCDHA5 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 22/676 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); called by muse, mutect2
- PCDHGA8 | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 118/259 reads (46%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PIP4P1 | c.729C>G p.I243M | Missense Mutation (SNP) | VAF 78/81 reads (96%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PLD2 | c.2774G>A p.G925D | Missense Mutation (SNP) | VAF 66/69 reads (96%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- POU3F3 | c.403C>A p.Q135K | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, varscan2
- PRKDC | c.479T>G p.L160R | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PROB1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 84/162 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRUNE1 | c.699G>T p.M233I | Missense Mutation (SNP) | VAF 72/162 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- PTPRD | c.3134A>T p.N1045I | Missense Mutation (SNP) | VAF 110/110 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); called by mutect2, varscan2
- RECQL | c.1592G>A p.G531D | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RP2 | c.860A>T p.D287V | Missense Mutation (SNP) | VAF 165/166 reads (99%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2
- SECISBP2 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.057); called by muse, mutect2
- SLC39A14 | c.1310T>C p.L437S | Missense Mutation (SNP) | VAF 80/86 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMARCC2 | c.3164A>C p.Q1055P | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.84); called by muse, mutect2
- SNX13 | c.1967del p.P656Lfs*3 | Frame Shift Del (DEL) | VAF 63/156 reads (40%) | called by mutect2, pindel
- SPHKAP | c.1667C>G p.S556C | Missense Mutation (SNP) | VAF 123/305 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STARD9 | c.9728A>G p.Q3243R | Missense Mutation (SNP) | VAF 135/299 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- SUGCT | c.1130C>T p.T377I (on ENST00000335693 / NM_001193313.2; = p.T403I on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/282 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SYT1 | c.160A>C p.I54L | Missense Mutation (SNP) | VAF 60/61 reads (98%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- THSD7B | c.2472A>T p.E824D | Missense Mutation (SNP) | VAF 117/295 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- TLN2 | c.7364G>A p.R2455K | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0.009); called by muse, mutect2
- TMCC2 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 210/457 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- TP53TG3D | c.*421-2A>C | Splice Site (SNP) | VAF 113/278 reads (41%) | called by muse, mutect2, varscan2
- TSHZ3 | c.2279A>C p.K760T | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TST | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 142/284 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- TTN | c.44468A>T p.K14823I (on ENST00000591111; = p.K7399I on NM_003319.4) | Missense Mutation (SNP) | VAF 25/45 reads (56%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UMODL1 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- WWC3 | c.2531T>C p.L844P | Missense Mutation (SNP) | VAF 144/148 reads (97%) | SIFT tolerated (0.35); PolyPhen benign (0.043); called by muse, varscan2
- ZFC3H1 | c.1268T>G p.V423G | Missense Mutation (SNP) | VAF 96/97 reads (99%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ZNF131 | c.1786G>A p.E596K (on ENST00000509156 / NM_001330707.2; = p.E562K on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/286 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF333 | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 91/297 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNF418 | c.598G>C p.D200H | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- ZNF436 | c.1294A>G p.N432D | Missense Mutation (SNP) | VAF 113/272 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- ZNF473 | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 109/246 reads (44%) | called by muse, mutect2, varscan2
- A2ML1 | c.3768C>T p.Y1256= | Silent (SNP) | VAF 234/379 reads (62%) | catalogued as rs1402696997, COSV55288880, COSV55297570; called by muse, mutect2, varscan2
- AMD1 | c.261G>A p.L87= | Silent (SNP) | VAF 22/303 reads (7%) | catalogued as rs1284561715, COSV64386891; called by muse, mutect2
- AMD1 | c.402A>C p.I134= | Silent (SNP) | VAF 16/186 reads (9%) | called by muse, mutect2
- ANKRD31 | c.2487T>G p.V829= | Silent (SNP) | VAF 91/206 reads (44%) | called by muse, mutect2, varscan2
- ANKRD52 | c.108G>A p.V36= | Silent (SNP) | VAF 12/106 reads (11%) | called by muse, varscan2
- ARHGAP27 | c.2298T>C p.V766= (on ENST00000428638 / NM_001282290.1; = p.V425= on NM_199282.3) | Silent (SNP) | VAF 54/123 reads (44%) | called by muse, mutect2, varscan2
- ATP5PD | c.276C>T p.A92= | Silent (SNP) | VAF 119/265 reads (45%) | catalogued as rs769443824, COSV56902311; called by muse, mutect2, varscan2
- CAVIN3 | c.567C>T p.L189= | Silent (SNP) | VAF 81/83 reads (98%) | called by muse, mutect2, varscan2
- CCDC50 | c.417T>A p.A139= | Silent (SNP) | VAF 161/337 reads (48%) | called by muse, mutect2, varscan2
- CHTF8 | c.96T>C p.T32= | Silent (SNP) | VAF 13/386 reads (3%) | called by muse, mutect2
- CKM | c.60C>T p.Y20= | Silent (SNP) | VAF 106/251 reads (42%) | called by muse, mutect2, varscan2
- CLK3 | c.870T>C p.G290= (on ENST00000395066 / NM_001130028.1; = p.G142= on NM_003992.4) | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as rs1323690218, COSV61411668; called by muse, mutect2, varscan2
- CNNM1 | c.825T>G p.V275= | Silent (SNP) | VAF 10/147 reads (7%) | called by muse, mutect2
- COL4A6 | c.4011C>A p.G1337= | Silent (SNP) | VAF 175/180 reads (97%) | called by muse, mutect2, varscan2
- COL6A5 | c.4893G>A p.E1631= | Silent (SNP) | VAF 123/289 reads (43%) | called by muse, mutect2, varscan2
- DDX6 | c.546A>G p.Q182= | Silent (SNP) | VAF 21/466 reads (5%) | catalogued as rs782712468, COSV50589477; called by muse, mutect2
- DNAAF3 | c.771C>G p.S257= (on ENST00000524407 / NM_001256715.2; = p.S304= on NM_178837.4) | Silent (SNP) | VAF 96/214 reads (45%) | catalogued as COSV61276650; called by muse, mutect2, varscan2
- DNAH5 | c.348C>T p.T116= | Silent (SNP) | VAF 182/404 reads (45%) | catalogued as rs775947029, COSV54251756; ClinVar: likely benign; called by muse, mutect2, varscan2
- EFHD2 | c.216C>A p.P72= | Silent (SNP) | VAF 27/699 reads (4%) | catalogued as COSV65658097; called by muse, mutect2
- EFHD2 | c.285G>A p.K95= | Silent (SNP) | VAF 24/604 reads (4%) | catalogued as COSV65658208; called by muse, mutect2
- EIF5 | c.303A>G p.E101= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs755543880; called by mutect2, varscan2
- FBXO41 | c.123C>T p.L41= | Silent (SNP) | VAF 14/352 reads (4%) | called by muse, mutect2
- FGF8 | c.219A>G p.Q73= (on ENST00000344255 / NM_033164.4; = p.Q55= on NM_006119.6) | Silent (SNP) | VAF 18/496 reads (4%) | catalogued as rs1564632353; called by muse, mutect2
- GALK1 | c.975G>A p.L325= | Silent (SNP) | VAF 213/504 reads (42%) | catalogued as rs1247403138; called by muse, mutect2, varscan2
- GNG5 | c.156A>G p.V52= | Silent (SNP) | VAF 22/152 reads (14%) | catalogued as COSV55364658; called by muse, mutect2
- GNRHR | c.150G>A p.A50= | Silent (SNP) | VAF 162/338 reads (48%) | catalogued as rs142057864; called by muse, mutect2, varscan2
- GRIA4 | c.2529A>G p.E843= | Silent (SNP) | VAF 17/511 reads (3%) | catalogued as COSV56879830, COSV99231698; called by muse, mutect2
- HERC1 | c.8013G>A p.E2671= | Silent (SNP) | VAF 73/75 reads (97%) | called by muse, mutect2, varscan2
- HIC1 | c.165C>T p.N55= (on ENST00000322941 / NM_001098202.1; = p.N36= on NM_006497.4) | Silent (SNP) | VAF 13/153 reads (8%) | catalogued as rs1166675422, COSV53964457; called by muse, mutect2
- HMCN1 | c.16254T>C p.T5418= | Silent (SNP) | VAF 131/250 reads (52%) | called by muse, mutect2, varscan2
- HMX3 | c.342A>G p.P114= | Silent (SNP) | VAF 8/196 reads (4%) | catalogued as rs1352015576; called by muse, mutect2
- HUWE1 | c.11662C>T p.L3888= | Silent (SNP) | VAF 12/283 reads (4%) | called by muse, mutect2
- IER5L | c.318C>T p.A106= | Silent (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- JADE3 | c.672C>T p.N224= | Silent (SNP) | VAF 85/86 reads (99%) | called by muse, mutect2, varscan2
- KHDC4 | c.1125A>G p.Q375= | Silent (SNP) | VAF 14/439 reads (3%) | catalogued as COSV64164468; called by muse, mutect2
- KIF20A | c.684A>C p.L228= | Silent (SNP) | VAF 113/207 reads (55%) | called by muse, mutect2, varscan2
- KIF3B | c.1293T>C p.D431= | Silent (SNP) | VAF 8/141 reads (6%) | catalogued as COSV65226803; called by muse, mutect2
- KIR3DL3 | c.195G>A p.G65= | Silent (SNP) | VAF 163/360 reads (45%) | called by muse, mutect2, varscan2
- KRT75 | c.1179G>A p.T393= | Silent (SNP) | VAF 217/226 reads (96%) | catalogued as rs751653300; called by muse, mutect2, varscan2
- LATS2 | c.1368G>A p.T456= | Silent (SNP) | VAF 43/43 reads (100%) | catalogued as rs1240800376; called by muse, mutect2, varscan2
- LHFPL3 | c.111C>T p.N37= | Silent (SNP) | VAF 38/340 reads (11%) | catalogued as COSV67804741; called by muse, varscan2
- LHFPL3 | c.234C>T p.G78= | Silent (SNP) | VAF 22/174 reads (13%) | catalogued as COSV67804761; called by muse, varscan2
- LIPI | c.972A>G p.Q324= | Silent (SNP) | VAF 65/151 reads (43%) | catalogued as rs767492356; called by muse, mutect2, varscan2
- MDFIC | c.705C>A p.I235= | Silent (SNP) | VAF 119/122 reads (98%) | called by muse, mutect2, varscan2
- MLLT3 | c.627A>G p.K209= | Silent (SNP) | VAF 19/330 reads (6%) | catalogued as COSV63494445; called by muse, mutect2
- MLLT6 | c.57G>A p.E19= | Silent (SNP) | VAF 11/247 reads (4%) | catalogued as rs1200137336; called by muse, mutect2
- MRPS15 | c.144G>A p.Q48= | Silent (SNP) | VAF 38/73 reads (52%) | called by muse, mutect2, varscan2
- MYH9 | c.1695A>G p.K565= | Silent (SNP) | VAF 8/17 reads (47%) | called by muse, varscan2
- MYL6 | c.109A>C p.R37= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as COSV52878182, COSV52879146; called by muse, mutect2
- NEBL | c.2943C>A p.I981= | Silent (SNP) | VAF 150/151 reads (99%) | called by muse, mutect2, varscan2
- NR1H2 | c.105G>A p.P35= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as rs1223912327; called by muse, mutect2, varscan2
- NRXN2 | c.1080T>C p.L360= | Silent (SNP) | VAF 21/644 reads (3%) | catalogued as COSV55455306; called by muse, mutect2
- NRXN2 | c.75C>T p.R25= | Silent (SNP) | VAF 66/108 reads (61%) | called by muse, varscan2
- NTRK3 | c.165C>T p.P55= | Silent (SNP) | VAF 18/575 reads (3%) | catalogued as COSV58108948; called by muse, mutect2
- OPCML | c.228C>T p.Y76= | Silent (SNP) | VAF 119/240 reads (50%) | catalogued as rs142071206; called by muse, mutect2, varscan2
- PABPC4 | c.558A>G p.K186= | Silent (SNP) | VAF 26/250 reads (10%) | called by muse, mutect2
- PCDHA9 | c.1650G>A p.T550= | Silent (SNP) | VAF 109/1023 reads (11%) | catalogued as rs781818027; called by muse, mutect2, varscan2
- PCDHGA4 | c.1614C>A p.I538= | Silent (SNP) | VAF 149/331 reads (45%) | called by muse, mutect2, varscan2
- PCSK5 | c.4674C>T p.Y1558= | Silent (SNP) | VAF 112/116 reads (97%) | catalogued as rs375144439; called by muse, mutect2, varscan2
- PRDM12 | c.891C>T p.R297= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as rs1485226225, COSV53390720; called by muse, mutect2
- PTP4A1 | c.52A>C p.R18= | Silent (SNP) | VAF 16/278 reads (6%) | catalogued as COSV65714915; called by muse, mutect2
- PURG | c.297C>T p.N99= | Silent (SNP) | VAF 7/137 reads (5%) | called by muse, mutect2
- RGPD3 | c.4767C>T p.A1589= | Silent (SNP) | VAF 131/708 reads (19%) | called by muse, mutect2, varscan2
- RGPD8 | c.2781G>A p.S927= | Silent (SNP) | VAF 215/704 reads (31%) | catalogued as rs752445460; called by muse, mutect2, varscan2
- RRAS2 | c.66G>T p.G22= | Silent (SNP) | VAF 12/157 reads (8%) | catalogued as rs1554955847; called by muse, mutect2
- SAMD1 | c.213C>G p.A71= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as COSV54115564; called by muse, varscan2
- SCML4 | c.423C>T p.C141= | Silent (SNP) | VAF 90/236 reads (38%) | catalogued as rs375948039; called by muse, mutect2, varscan2
- SERPINC1 | c.708G>A p.S236= | Silent (SNP) | VAF 177/368 reads (48%) | catalogued as rs774632265, COSV62928812; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SFRP1 | c.264G>A p.A88= | Silent (SNP) | VAF 15/329 reads (5%) | catalogued as COSV55174722; called by muse, mutect2
- SIX3 | c.288T>C p.C96= | Silent (SNP) | VAF 17/388 reads (4%) | catalogued as COSV53227290; called by muse, mutect2
- SLC52A1 | c.363G>A p.L121= | Silent (SNP) | VAF 133/140 reads (95%) | called by muse, mutect2, varscan2
- SNTB2 | c.450T>G p.A150= | Silent (SNP) | VAF 14/280 reads (5%) | catalogued as rs1197353929, COSV60352376; called by muse, mutect2
- SOX3 | c.432C>T p.N144= | Silent (SNP) | VAF 128/134 reads (96%) | catalogued as rs1220108057; called by muse, mutect2, varscan2
- SOX30 | c.552C>T p.G184= | Silent (SNP) | VAF 159/295 reads (54%) | called by muse, mutect2, varscan2
- SRSF10 | c.627T>G p.S209= | Silent (SNP) | VAF 20/400 reads (5%) | called by muse, mutect2
- SUCLG2 | c.294T>C p.S98= | Silent (SNP) | VAF 6/101 reads (6%) | catalogued as rs1463164762; called by muse, mutect2
- SUV39H2 | c.69T>C p.L23= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- TAF1L | c.4632T>C p.S1544= | Silent (SNP) | VAF 132/137 reads (96%) | called by muse, mutect2, varscan2
- TECTA | c.3291C>T p.D1097= | Silent (SNP) | VAF 250/254 reads (98%) | catalogued as rs763928462, COSV50689414; ClinVar: likely benign; called by muse, mutect2, varscan2
- TET1 | c.2637G>A p.S879= | Silent (SNP) | VAF 64/143 reads (45%) | catalogued as rs574835128, COSV101018497; called by muse, mutect2, varscan2
- TEX33 | c.180C>A p.G60= | Silent (SNP) | VAF 51/51 reads (100%) | catalogued as rs541106060; called by muse, mutect2, varscan2
- TFAP2D | c.826T>C p.L276= | Silent (SNP) | VAF 196/196 reads (100%) | catalogued as COSV99147357, COSV99148083; called by muse, mutect2, varscan2
- TMED2 | c.525T>C p.F175= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV51630178; called by muse, mutect2, varscan2
- TMEM178A | c.162C>T p.D54= | Silent (SNP) | VAF 26/448 reads (6%) | catalogued as rs1196821763, COSV56142368; called by muse, mutect2
- TMEM266 | c.270G>A p.V90= | Silent (SNP) | VAF 11/163 reads (7%) | catalogued as COSV101189641; called by muse, mutect2
- TNR | c.834C>T p.N278= | Silent (SNP) | VAF 170/351 reads (48%) | catalogued as rs973131663, COSV54895816, COSV54902862; called by muse, mutect2, varscan2
- TRIB2 | c.24C>T p.P8= | Silent (SNP) | VAF 9/200 reads (5%) | catalogued as COSV50224260; called by muse, mutect2
- TTN | c.44469A>G p.K14823= (on ENST00000591111; = p.K7399= on NM_003319.4) | Silent (SNP) | VAF 26/46 reads (57%) | called by muse, mutect2, varscan2
- TUSC3 | c.783A>C p.P261= | Silent (SNP) | VAF 86/87 reads (99%) | called by muse, mutect2, varscan2
- UNC5D | c.846A>C p.P282= | Silent (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- USP6 | c.822C>T p.D274= | Silent (SNP) | VAF 272/282 reads (96%) | catalogued as rs779071655, COSV51474165; called by muse, mutect2, varscan2
- VAMP7 | c.33G>A p.G11= | Silent (SNP) | VAF 8/135 reads (6%) | catalogued as rs773234929; called by muse, mutect2
- VPS37D | c.612C>T p.A204= | Silent (SNP) | VAF 68/132 reads (52%) | called by muse, mutect2
- YBX1 | c.879A>G p.E293= | Silent (SNP) | VAF 26/498 reads (5%) | catalogued as COSV58437164; called by muse, mutect2
- YTHDF3 | c.846A>G p.K282= | Silent (SNP) | VAF 7/158 reads (4%) | catalogued as COSV101572439, COSV72773170; called by muse, mutect2
- ZFAT | c.597C>T p.I199= | Silent (SNP) | VAF 86/202 reads (43%) | catalogued as COSV100915184; called by muse, varscan2
- ZFYVE9 | c.2391T>C p.A797= | Silent (SNP) | VAF 7/107 reads (7%) | catalogued as rs982951593, COSV55089889; called by muse, mutect2
- ZNF148 | c.564A>G p.R188= | Silent (SNP) | VAF 8/196 reads (4%) | catalogued as rs1219114830; called by muse, mutect2
- ZNF282 | c.52C>T p.L18= | Silent (SNP) | VAF 11/314 reads (4%) | catalogued as rs1426928439, COSV50481660; called by muse, mutect2
- ZNF790 | c.1296T>G p.T432= | Silent (SNP) | VAF 37/86 reads (43%) | called by muse, mutect2, varscan2
- AL603840.1 | n.990T>G | RNA (SNP) | VAF 7/8 reads (88%) | catalogued as rs1303133707; called by muse, mutect2, varscan2
- ARFRP1 | c.264+595G>A | Intron (SNP) | VAF 72/147 reads (49%) | catalogued as rs933627268; called by muse, mutect2, varscan2
- ARIH1 | c.912-17T>C | Intron (SNP) | VAF 62/63 reads (98%) | catalogued as rs1486098499; called by muse, mutect2, varscan2
- ATE1 | c.942+940C>T | Intron (SNP) | VAF 99/224 reads (44%) | catalogued as rs776555663; called by muse, mutect2, varscan2
- ATP2B1 | c.3351+430G>A | Intron (SNP) | VAF 8/191 reads (4%) | catalogued as COSV53803510; called by muse, mutect2
- CHRM2 | c.-47+33809A>G | Intron (SNP) | VAF 159/162 reads (98%) | called by muse, mutect2, varscan2
- CIDEA | c.38+309G>A | Intron (SNP) | VAF 261/420 reads (62%) | called by muse, mutect2, varscan2
- CXCL12 | c.266+2629del | Intron (DEL) | VAF 132/389 reads (34%) | catalogued as COSV100639012; called by mutect2, pindel, varscan2
- CYP2R1 | c.226-46C>G | Intron (SNP) | VAF 65/68 reads (96%) | called by muse, mutect2, varscan2
- DCHS2 | n.6159C>A | RNA (SNP) | VAF 45/93 reads (48%) | called by muse, mutect2, varscan2
- DNAJB6 | c.691+9C>T | Intron (SNP) | VAF 31/194 reads (16%) | called by muse, mutect2, varscan2
- DNMT3A | c.1937-25C>T | Intron (SNP) | VAF 130/258 reads (50%) | catalogued as rs773723532; called by muse, mutect2, varscan2
- ELAVL2 | c.-12-2790T>G | Intron (SNP) | VAF 142/156 reads (91%) | catalogued as COSV99805515; called by muse, varscan2
- EP400 | c.1335+1595A>C | Intron (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- FABP12 | c.-4C>T | 5'UTR (SNP) | VAF 70/148 reads (47%) | catalogued as rs371517951; called by muse, mutect2, varscan2
- FOXP2 | c.*671T>A | 3'UTR (SNP) | VAF 10/198 reads (5%) | called by muse, mutect2
- GRM6 | c.2125-224G>T | Intron (SNP) | VAF 162/340 reads (48%) | called by muse, mutect2, varscan2
- HEG1 | c.1589-908G>A | Intron (SNP) | VAF 47/124 reads (38%) | called by muse, mutect2, varscan2
- HLX | c.*34G>A | 3'UTR (SNP) | VAF 75/143 reads (52%) | catalogued as rs753006825; called by muse, mutect2, varscan2
- HMCN1 | c.*36G>A | 3'UTR (SNP) | VAF 102/239 reads (43%) | catalogued as rs558323454, COSV54920802; called by muse, mutect2, varscan2
- HOXC9 | c.-7C>T | 5'UTR (SNP) | VAF 19/178 reads (11%) | called by muse, mutect2, varscan2
- INTS11 | c.429+76_429+77del | Intron (DEL) | VAF 68/186 reads (37%) | catalogued as rs779096754; called by pindel, varscan2
- KIF5A | c.1905+38G>A | Intron (SNP) | VAF 24/144 reads (17%) | called by muse, mutect2, varscan2
- KLHL4 | c.*2832A>G | 3'UTR (SNP) | VAF 92/96 reads (96%) | catalogued as COSV64138970; called by muse, mutect2, varscan2
- KMT2C | c.11670+967A>G | Intron (SNP) | VAF 18/158 reads (11%) | called by muse, varscan2
- MACROD2 | c.-2A>G | 5'UTR (SNP) | VAF 18/282 reads (6%) | catalogued as rs1283738390, COSV53966164; called by muse, mutect2
- MFF | c.-19C>T | 5'UTR (SNP) | VAF 62/189 reads (33%) | called by muse, mutect2
- MIR212 | n.66C>T | RNA (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- MIR6511A4 | chr16:18347953 G>A | 5'Flank (SNP) | VAF 90/1050 reads (9%) | catalogued as rs755794468; called by muse, mutect2
- MSLN | c.1807+15C>T | Intron (SNP) | VAF 128/209 reads (61%) | called by muse, mutect2, varscan2
- MTRNR2L9 | n.59T>C | RNA (SNP) | VAF 96/96 reads (100%) | called by muse, mutect2, varscan2
- NFATC4 | chr14:24367395 C>T | 5'Flank (SNP) | VAF 20/113 reads (18%) | called by muse, mutect2, varscan2
- NPAT | c.38-11062C>T | Intron (SNP) | VAF 100/198 reads (51%) | called by muse, mutect2, varscan2
- PCBP2 | c.592-45C>G | Intron (SNP) | VAF 14/178 reads (8%) | called by muse, mutect2
- PCBP2 | c.1061+3351G>A | Intron (SNP) | VAF 11/118 reads (9%) | catalogued as COSV63728947; called by muse, mutect2
- PDGFC | c.119-11046T>G | Intron (SNP) | VAF 53/119 reads (45%) | called by muse, mutect2, varscan2
- POTEG | c.811-1061C>A | Intron (SNP) | VAF 10/40 reads (25%) | called by mutect2, varscan2
- PPP2R2B | c.-59A>T | 5'UTR (SNP) | VAF 24/405 reads (6%) | catalogued as COSV60768468; called by muse, mutect2
- RASGRP2 | c.371+68G>A | Intron (SNP) | VAF 152/306 reads (50%) | catalogued as rs758856294; called by muse, mutect2, varscan2
- RTN4R | c.22+392G>A | Intron (SNP) | VAF 128/132 reads (97%) | called by muse, mutect2, varscan2
- SMOC2 | c.1323+668G>A | Intron (SNP) | VAF 182/185 reads (98%) | catalogued as COSV62437578; called by muse, mutect2, varscan2
- SON | c.*68T>A | 3'UTR (SNP) | VAF 11/187 reads (6%) | called by muse, mutect2
- SYNC | c.*19G>C | 3'UTR (SNP) | VAF 85/244 reads (35%) | catalogued as COSV100995364; called by muse, mutect2, varscan2
- TRIM41 | c.909+16C>T | Intron (SNP) | VAF 96/212 reads (45%) | catalogued as rs775308937; called by muse, mutect2, varscan2
- WASH2P | n.1583C>A | RNA (SNP) | VAF 102/465 reads (22%) | called by muse, mutect2, varscan2
